Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7611, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7611-01A (Primary Tumor).

path report

Microscopic

Sections demonstrate a mildly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The nuclei are consistently round, smooth walled and small. However, a few scattered larger round nuclei are seen. No perinuclear halos are noted. The tumor cells appear to have fine fibrillary processes. On slide 2B, a microgemistocytic pattern is seen focally. There is no mitotic activity, microvascular proliferation or necrosis.

Diagnosis

Low grade oligoastrocytoma

Source: NCI Genomic Data Commons file 8d89226e-8efc-4c8e-a4e0-76c97358d994 (TCGA-HT-7611.3010CC40-0D85-403E-B6FA-D4EE92F58ECB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).